Somatic mutation profile of tumor specimen TCGA-XF-AAN7-01A (aliquot TCGA-XF-AAN7-01A-11D-A42E-08) from TCGA case TCGA-XF-AAN7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 60.1 years (21,951 days).
Specimen TCGA-XF-AAN7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51849cf4-ed5b-4e92-b015-419fea0123da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XF-AAN7-10A (Blood Derived Normal), aliquot TCGA-XF-AAN7-10A-01D-A42H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3c93100-3d5c-4555-a81f-899058b16fb9

The open-access MAF lists 163 somatic variants for this specimen: 124 protein-altering or splice-affecting, 39 silent.
By variant classification: Missense Mutation 106, Silent 39, Nonsense Mutation 9, Frame Shift Del 7, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 51/58 reads (88%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.2501C>A p.S834* | Nonsense Mutation (SNP) | VAF 52/61 reads (85%) | catalogued as rs1131690906, CM144782, CM952105, COSV57310865, COSV99925872; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 31/34 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs193920817, COSV52660939, COSV52789715, COSV53470581; ClinVar: conflicting interpretations of pathogenicity / uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AGAP3 | c.1472G>A p.G491E (on ENST00000622464; = p.G527E on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as COSV101257313, COSV68246310; called by muse, mutect2, varscan2
- AGBL1 | c.3093G>A p.M1031I | Missense Mutation (SNP) | VAF 5/8 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV101223901; called by muse, mutect2, varscan2
- AKR1D1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs146708783, COSV54341545; called by muse, mutect2
- ALDOA | c.490G>A p.D164N (on ENST00000642816 / NM_001243177.4; = p.D110N on NM_184041.5) | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV57632011, COSV57634029; called by muse, mutect2, varscan2
- ATRX | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 161/178 reads (90%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as COSV64878775; called by muse, mutect2, varscan2
- ATXN2L | c.1231A>G p.K411E | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.971); catalogued as rs1374349578, COSV57378943; called by muse, mutect2, varscan2
- C3 | c.3656G>A p.R1219H | Missense Mutation (SNP) | VAF 43/89 reads (48%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as rs369542526, COSV55573665; called by muse, mutect2, varscan2
- C8B | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs761533195, COSV64777481; called by muse, mutect2, varscan2
- CACNA1E | c.4781G>A p.R1594H | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436277931, COSV62382452; called by muse, mutect2, varscan2
- CAT | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV53813422; called by muse, mutect2, varscan2
- CATSPER1 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV56413574; called by muse, mutect2, varscan2
- CD2AP | c.23A>G p.Y8C | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413605047, COSV63761559; called by muse, mutect2, varscan2
- CDC20 | c.128T>A p.M43K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV60523086; called by muse, mutect2, varscan2
- CDCA2 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 74/131 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.278); catalogued as COSV57948189; called by muse, mutect2, varscan2
- CEP170 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV60514908; called by muse, varscan2
- CERT1 | c.1022A>G p.D341G (on ENST00000405807 / NM_001130105.1; = p.D213G on NM_005713.3) | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.38); catalogued as COSV54664875; called by muse, mutect2, varscan2
- CIRBP | c.322C>T p.R108* | Nonsense Mutation (SNP) | VAF 19/67 reads (28%) | catalogued as rs774624754, COSV100309731; called by muse, mutect2, varscan2
- CLIP2 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as rs782311150, COSV99791941; called by muse, mutect2
- CNTN4 | c.1911del p.F638Sfs*27 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | catalogued as COSV61881403; called by mutect2, pindel, varscan2
- COL14A1 | c.3556G>A p.A1186T | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs775543009, COSV52846651; called by muse, mutect2, varscan2
- COPS4 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.27); catalogued as rs1429201037, COSV52317492; called by muse, mutect2, varscan2
- CPN2 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV60471995; called by muse, mutect2, varscan2
- CTCF | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV50461847, COSV99866082; called by muse, mutect2, varscan2
- CXXC4 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67296965; called by muse, mutect2, varscan2
- CYP3A5 | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 42/57 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.812); catalogued as COSV56123230; called by muse, mutect2, varscan2
- DAB2IP | c.2530C>T p.R844C (on ENST00000408936; = p.R816C on NM_032552.3) | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1254306609, COSV52262732; called by muse, mutect2, varscan2
- DCLRE1C | c.623C>A p.A208E (on ENST00000378278 / NM_001350965.2; = p.A93E on NM_022487.4) | Missense Mutation (SNP) | VAF 58/66 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100739789, COSV63185496; called by muse, mutect2, varscan2
- DCT | c.327C>G p.C109W | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV65470764; called by muse, mutect2, varscan2
- DPF2 | c.893G>A p.C298Y | Missense Mutation (SNP) | VAF 37/67 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52891414; called by muse, mutect2, varscan2
- EIF3B | c.1763C>A p.S588Y | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62803372, COSV62805029; called by muse, mutect2, varscan2
- EIPR1 | c.793G>A p.V265M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs149049035; called by muse, mutect2, varscan2
- F7 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60648281; called by muse, mutect2, varscan2
- FAM184A | c.3071G>T p.R1024L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775538811, COSV58858888; called by muse, mutect2, varscan2
- FTSJ3 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV63791453; called by muse, mutect2, varscan2
- GDPD4 | c.363G>A p.W121* | Nonsense Mutation (SNP) | VAF 7/25 reads (28%) | catalogued as COSV60021289; called by muse, mutect2, varscan2
- GLI2 | c.379del p.E127Sfs*15 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | catalogued as COSV58042216; called by mutect2, pindel, varscan2
- GOLGA2 | c.185A>G p.N62S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs776699882, COSV70168908; called by muse, mutect2, varscan2
- GPC5 | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV65630572, COSV99058154; called by muse, mutect2, varscan2
- GUCY1A1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.89); PolyPhen benign (0.054); catalogued as COSV56656628; called by muse, mutect2, varscan2
- IL22RA2 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV51664144, COSV51664794; called by muse, mutect2, varscan2
- ISG20 | c.329C>G p.T110R | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100044121, COSV60144548; called by muse, mutect2, varscan2
- KANSL1 | c.2623C>T p.R875C (on ENST00000574590 / NM_001193465.2; = p.R876C on NM_015443.4) | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52274198; called by muse, mutect2, varscan2
- KCNB2 | c.2530C>T p.P844S | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs1476787455, COSV101578888; called by muse, mutect2
- KCTD10 | c.28G>T p.V10L | Missense Mutation (SNP) | VAF 29/30 reads (97%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.355); catalogued as COSV57328092, COSV57328384; called by muse, mutect2, varscan2
- KRT33B | c.1027C>A p.L343M | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV52442493; called by muse, mutect2, varscan2
- L3MBTL3 | c.1295A>G p.H432R | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.05); catalogued as COSV62389024; called by muse, mutect2, varscan2
- LCA5 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV63973125; called by muse, mutect2, varscan2
- LCN8 | c.430G>A p.G144R (on ENST00000612714 / NM_001345934.1; = p.G121R on NM_178469.3) | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60211357; called by muse, mutect2, varscan2
- LCT | c.1898A>T p.H633L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51557619; called by muse, mutect2, varscan2
- LRMDA | c.46A>G p.R16G | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as rs1425367618, COSV65284096; called by muse, mutect2, varscan2
- LRP1 | c.7984C>T p.R2662W | Missense Mutation (SNP) | VAF 48/58 reads (83%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.567); catalogued as rs1051416622, COSV54506215, COSV54526167; called by muse, mutect2, varscan2
- LUZP2 | c.159T>A p.D53E | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.051); catalogued as rs764140550, COSV61219050; called by muse, mutect2
- MAP3K15 | c.3487A>G p.T1163A | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100135271; called by muse, mutect2
- MAP3K21 | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 21/34 reads (62%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs760993530, COSV100786116, COSV64042655; called by muse, mutect2, varscan2
- MIER1 | c.1429A>G p.K477E (on ENST00000355356 / NM_001077701.3; = p.K494E on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62532253; called by muse, mutect2, varscan2
- MPPED2 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.157); catalogued as COSV63901332; called by muse, mutect2, varscan2
- N4BP2L2 | c.332C>T p.S111F | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV57230284; called by muse, mutect2, varscan2
- NLGN1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV64347229; called by muse, mutect2, varscan2
- NOTCH1 | c.6355G>A p.V2119M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53095726; called by muse, mutect2, varscan2
- NT5C1A | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99348586; called by muse, mutect2, varscan2
- NUP205 | c.4421G>A p.G1474D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV53666193; called by muse, mutect2, varscan2
- NUP62 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100351989, COSV61311455; called by muse, mutect2, varscan2
- OR4A16 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.082); catalogued as rs575051490, COSV59042137; called by muse, mutect2, varscan2
- OR4A16 | c.359G>T p.R120L | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.136); catalogued as rs779328620, COSV59041859, COSV59045144; called by muse, mutect2, varscan2
- OR51A4 | c.847C>T p.L283F | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV66750092; called by muse, mutect2
- OR51M1 | c.155C>T p.S52L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.149); catalogued as COSV60785319; called by muse, mutect2, varscan2
- OR56A4 | c.164C>T p.S55F | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.019); catalogued as COSV58111728; called by muse, mutect2, varscan2
- OR8K3 | c.581A>T p.E194V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.367); catalogued as COSV57133197; called by muse, mutect2, varscan2
- PAPOLA | c.28T>C p.S10P | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV53485516; called by muse, mutect2
- PCDH12 | c.1762C>A p.L588M | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV51524860; called by muse, mutect2, varscan2
- PCDH15 | c.783G>T p.L261F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV57272474, COSV57396474; called by muse, mutect2, varscan2
- PCLO | c.5973A>T p.Q1991H | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.443); catalogued as COSV61667079; called by muse, mutect2, varscan2
- PCNX3 | c.3889G>A p.V1297I | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.074); catalogued as rs781436467, COSV63140916; called by muse, mutect2, varscan2
- PDE6G | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.553); catalogued as rs144191975; called by muse, varscan2
- PKDREJ | c.4945T>C p.W1649R | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53553303; called by muse, mutect2, varscan2
- PLA2G4C | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs779460960, COSV62787992; called by muse, mutect2, varscan2
- PLEKHO1 | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 46/63 reads (73%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1553818751, COSV50311425; called by muse, mutect2, varscan2
- POLM | c.671A>G p.E224G | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54244006; called by muse, mutect2, varscan2
- PRSS12 | c.803C>T p.T268M | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.04); catalogued as rs749085303, COSV56610543; called by muse, mutect2, varscan2
- PSMA3 | c.758A>G p.D253G | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1463078022, COSV53618498; called by muse, mutect2, varscan2
- PXDNL | c.2284C>T p.R762C | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as rs1390725251, COSV62485704; called by muse, mutect2, varscan2
- RBM42 | c.433C>T p.R145W | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as rs538251490, COSV52898131; called by muse, mutect2, varscan2
- RDH8 | c.920G>A p.R307H (on ENST00000651512; = p.R287H on NM_015725.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs911312567, COSV50674873; called by muse, mutect2, varscan2
- RNF208 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 10/12 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); catalogued as rs1051891700, COSV100763166; called by muse, mutect2, varscan2
- RPUSD3 | c.275C>T p.T92M | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs749852634, COSV67579206; called by muse, mutect2, varscan2
- RRS1 | c.1042_1043del p.G348Lfs*28 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | catalogued as COSV52559241; called by mutect2, pindel, varscan2
- RUNX1 | c.812del p.P271Qfs*13 (on ENST00000344691 / NM_001001890.3; = p.P298Qfs*13 on NM_001754.5) | Frame Shift Del (DEL) | VAF 35/63 reads (56%) | catalogued as COSV100276801; called by mutect2, pindel, varscan2
- SAGE1 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 68/77 reads (88%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.961); catalogued as COSV61018145; called by muse, mutect2, varscan2
- SCPEP1 | c.409A>G p.M137V | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs530198332, COSV51855657; called by muse, mutect2, varscan2
- SEMA3D | c.1610A>T p.Y537F | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV52404951; called by muse, mutect2, varscan2
- SF1 | c.697C>G p.P233A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV57117518; called by muse, mutect2, varscan2
- SGCA | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV56251126; called by muse, mutect2, varscan2
- SMARCE1 | c.228C>G p.Y76* | Nonsense Mutation (SNP) | VAF 18/45 reads (40%) | catalogued as COSV100796035; called by muse, mutect2, varscan2
- SPTA1 | c.62C>A p.A21E | Missense Mutation (SNP) | VAF 62/79 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV63756909; called by muse, mutect2, varscan2
- SYCP2 | c.4304T>C p.L1435S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62772663; called by muse, mutect2, varscan2
- TAF1 | c.3785A>G p.Y1262C (on ENST00000373790 / NM_138923.4; = p.Y1283C on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/34 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV52125886; called by muse, mutect2, varscan2
- TENM3 | c.4841G>T p.S1614I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV101305303; called by muse, mutect2
- TMEM117 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs758993698, COSV56900727; called by mutect2, varscan2
- TUBD1 | c.1101T>G p.Y367* | Nonsense Mutation (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100360197; called by muse, mutect2, varscan2
- TUT7 | c.1873A>C p.T625P | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52899070; called by muse, mutect2, varscan2
- UBA3 | c.1191G>A p.M397I | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.206); catalogued as COSV100734743; called by muse, mutect2, varscan2
- UNC13C | c.1090G>T p.G364* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99520998; called by muse, mutect2, varscan2
- VWF | c.7676C>T p.S2559L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs778732929, COSV54611097; called by muse, mutect2, varscan2
- XPOT | c.2320G>C p.E774Q | Missense Mutation (SNP) | VAF 82/152 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV60348403; called by muse, mutect2, varscan2
- ZCCHC14 | c.805G>A p.G269S (on ENST00000268616; = p.G406S on NM_015144.3) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV51890484; called by muse, mutect2, varscan2
- ZDBF2 | c.2296C>T p.H766Y | Missense Mutation (SNP) | VAF 52/97 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV65630114; called by muse, mutect2, varscan2
- ZNF17 | c.1613A>T p.N538I | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV56922573; called by muse, mutect2, varscan2
- ZNF202 | c.831G>A p.L277= | Splice Region (SNP) | VAF 11/41 reads (27%) | catalogued as COSV60248650; called by muse, mutect2, varscan2
- ZNF217 | c.691C>G p.L231V | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748086506, COSV56600969; called by muse, mutect2, varscan2
- ZNF229 | c.1784C>T p.T595M | Missense Mutation (SNP) | VAF 27/50 reads (54%) | SIFT deleterious (0.05); PolyPhen benign (0.399); catalogued as rs907144421, COSV52162819; called by muse, mutect2, varscan2
- ZNF423 | c.448T>C p.F150L (on ENST00000563137 / NM_001379286.1; = p.F142L on NM_015069.4) | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52205012; called by muse, mutect2, varscan2
- ZNF433 | c.1139C>G p.S380* | Nonsense Mutation (SNP) | VAF 17/56 reads (30%) | catalogued as COSV100795029, COSV61400183; called by muse, mutect2, varscan2
- ZNF440 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58372575; called by muse, mutect2, varscan2
- ZNF721 | c.227A>G p.K76R (on ENST00000338977; = p.K88R on NM_133474.4) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.05); catalogued as rs747724157, COSV59090105; called by muse, mutect2, varscan2
- ZNF761 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.314); catalogued as COSV61889519; called by muse, mutect2, varscan2
- ZNF804A | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV56471929; called by muse, mutect2, varscan2
- ZNF91 | c.1153A>G p.K385E | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV56093340; called by muse, mutect2, varscan2
- HBEGF | c.385del p.A129Lfs*18 | Frame Shift Del (DEL) | VAF 31/83 reads (37%) | called by mutect2, pindel, varscan2
- PPM1B | c.593dup p.S199Ifs*8 | Frame Shift Ins (INS) | VAF 28/52 reads (54%) | called by mutect2, pindel, varscan2
- SLCO3A1 | c.1458_1459del p.C486Wfs*32 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by pindel, varscan2
- TADA2A | c.668del p.I224Lfs*2 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, pindel, varscan2
- ACSL1 | c.669C>T p.I223= | Silent (SNP) | VAF 40/72 reads (56%) | catalogued as COSV55666606; called by muse, mutect2, varscan2
- ACTL6B | c.477C>T p.N159= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs545175553, COSV50513802; called by muse, varscan2
- ACVR2A | c.1047T>G p.A349= | Silent (SNP) | VAF 11/61 reads (18%) | catalogued as COSV54029187; called by muse, mutect2
- ADCK1 | c.1128G>A p.L376= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as COSV53086081; called by muse, mutect2, varscan2
- ADCY8 | c.1287C>G p.T429= | Silent (SNP) | VAF 11/22 reads (50%) | catalogued as rs764480857, COSV53910055, COSV53928293; called by muse, mutect2, varscan2
- ALDOA | c.582G>A p.K194= (on ENST00000642816 / NM_001243177.4; = p.K140= on NM_184041.5) | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs746865548, COSV57634039; called by muse, mutect2, varscan2
- ARID1A | c.4599G>A p.L1533= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV61389296; called by muse, mutect2, varscan2
- CD6 | c.1755C>T p.P585= | Silent (SNP) | VAF 19/50 reads (38%) | catalogued as COSV57837332, COSV57842824; called by muse, mutect2, varscan2
- DCX | c.999C>T p.P333= (on ENST00000636035 / NM_001195553.2; = p.P328= on NM_000555.3) | Silent (SNP) | VAF 14/14 reads (100%) | catalogued as COSV57575443; called by muse, mutect2, varscan2
- ENPP1 | c.2211C>T p.Y737= | Silent (SNP) | VAF 44/76 reads (58%) | catalogued as rs376128399; called by muse, mutect2, varscan2
- EXOC6B | c.228G>A p.V76= | Silent (SNP) | VAF 56/95 reads (59%) | catalogued as COSV55573163; called by muse, mutect2, varscan2
- FAM117B | c.819T>C p.S273= | Silent (SNP) | VAF 30/49 reads (61%) | catalogued as COSV57422425; called by muse, mutect2, varscan2
- FAT3 | c.7390C>T p.L2464= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as COSV53175450; called by muse, mutect2, varscan2
- FFAR4 | c.576G>T p.S192= | Silent (SNP) | VAF 35/79 reads (44%) | catalogued as COSV65179838; called by muse, mutect2, varscan2
- FKBP7 | c.624C>T p.F208= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs1345657205, COSV51847624; called by muse, mutect2, varscan2
- FRYL | c.8877G>A p.Q2959= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as COSV51962723; called by muse, mutect2, varscan2
- GFRA1 | c.1392A>T p.T464= | Silent (SNP) | VAF 12/23 reads (52%) | catalogued as COSV62610935; called by muse, mutect2, varscan2
- GKN2 | c.513G>A p.L171= | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV61032028; called by muse, mutect2, varscan2
- GLRA2 | c.528G>A p.L176= | Silent (SNP) | VAF 43/64 reads (67%) | catalogued as COSV54347791; called by muse, mutect2, varscan2
- IL4R | c.129T>G p.T43= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as COSV50175027; called by muse, mutect2, varscan2
- KIF2B | c.1800A>G p.T600= | Silent (SNP) | VAF 37/56 reads (66%) | catalogued as COSV52135453; called by muse, mutect2, varscan2
- LRRC52 | c.183C>T p.N61= | Silent (SNP) | VAF 77/109 reads (71%) | catalogued as rs150814230, COSV54233282; called by muse, mutect2, varscan2
- NEK5 | c.1869G>A p.K623= | Silent (SNP) | VAF 17/19 reads (89%) | catalogued as COSV62882021; called by muse, mutect2, varscan2
- OR4Q3 | c.747T>C p.C249= | Silent (SNP) | VAF 23/41 reads (56%) | catalogued as COSV59180412; called by muse, mutect2, varscan2
- OR5P2 | c.657C>T p.I219= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as COSV61491320; called by muse, mutect2
- PARP8 | c.432T>C p.Y144= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs185929571, COSV55867079; called by muse, mutect2, varscan2
- PARP8 | c.1810C>A p.R604= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV55858788, COSV55867093; called by muse, mutect2, varscan2
- PCDHA6 | c.1527G>A p.S509= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs782664739, COSV65342190; called by muse, mutect2, varscan2
- PGAP1 | c.558G>A p.L186= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs1172393880, COSV61326795; called by muse, mutect2, varscan2
- PUS1 | c.684G>T p.T228= | Silent (SNP) | VAF 24/26 reads (92%) | catalogued as COSV59036607; called by muse, mutect2, varscan2
- SIM1 | c.1452C>T p.A484= | Silent (SNP) | VAF 31/53 reads (58%) | catalogued as rs779506359, COSV53491122; called by muse, mutect2, varscan2
- SMAD4 | c.1218G>T p.A406= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as COSV61694986; called by muse, mutect2, varscan2
- TCFL5 | c.1308G>A p.K436= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV53899199; called by muse, mutect2, varscan2
- THBS2 | c.1980C>T p.H660= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs746875278, COSV100828170, COSV64681234, COSV64682248; called by muse, mutect2, varscan2
- TMEM38B | c.345G>C p.S115= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as COSV101016528, COSV65951474; called by muse, mutect2, varscan2
- TOX | c.225T>A p.P75= | Silent (SNP) | VAF 9/84 reads (11%) | catalogued as COSV63850707; called by muse, mutect2, varscan2
- TSGA10IP | c.681G>A p.R227= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs779007139, COSV101598419; called by muse, mutect2, varscan2
- UNC5CL | c.537C>G p.L179= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV55109759, COSV55109990, COSV55112067; called by muse, varscan2
- XPO1 | c.1797C>T p.F599= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs371003962; called by muse, mutect2, varscan2
